Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7062, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7062-01A (Primary Tumor).

[page 1 of 2]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Bilateral renal mass, right cystic mass left solid mass consistent with neoplasm

Specimens Submitted:

1: Kidney, left; partial nephrectomy

DIAGNOSIS:

1. Kidney, left; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Papillary type

Type II with eosinophilic cytoplasm and focally high grade nuclei

Tumor Size:

Greatest diameter is 3.8 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Glomerular and vascular changes morphologically compatible with (PAS stain examined)

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

[page 2 of 2]
Special Studies:

Result

Special Stain
PAS

Comment

Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "left renal mass, freeze margin". It consists of a 5.0 x 4.9 x 3.1 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a yellow brown granular tumor measuring 3.8 x 3.0 x 2.7 cm, with an adjacent thin rim of red-brown renal parenchyma. The clearance from the resection margin is 0.3 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Additional representative sections are submitted for TPS and routine processing.

Summary of sections:

FSC - frozen section control

TM - tumor to margin

T-tumor

RS - representative sections

Summary of Sections:

Part 1: Kidney, left; partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	RS	1
1	T	1
2	TM	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Left renal mass (fs): Renal cortical neoplasm, margin benign
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file 2d61efd6-4f22-49ff-9f13-4e5fec609cb5 (TCGA-BQ-7062.67818D6B-E29D-4775-9DF2-070959ADADD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).